Somatic mutation profile of tumor specimen 0DM1K0 from CCDI case PBCADE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroepithelioma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 10.4 years (3,788 days).
Specimen 0DM1K0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b1032d7-3d1d-4e13-b96e-cb6d504bc50a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM1JG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6db303f5-8193-4b62-a314-7c7041f1aff5

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 4, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP11A | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 216/584 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1417105477, COSV52107059; called by muse, mutect2, varscan2
- FGFR4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 269/653 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777645394, COSV99449475; called by muse, mutect2, varscan2
- KCNQ5 | c.1433G>A p.R478H | Missense Mutation (SNP) | VAF 309/1332 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59678539; called by muse, mutect2, varscan2
- GAS8 | c.120G>T p.E40D | Missense Mutation (SNP) | VAF 251/723 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PITPNM2 | c.2926_2931dup p.E976_V977dup | In Frame Ins (INS) | VAF 262/742 reads (35%) | called by mutect2, varscan2
- PKHD1L1 | c.4481G>T p.G1494V | Missense Mutation (SNP) | VAF 260/878 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- RFXAP | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 205/475 reads (43%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- C6orf132 | c.549G>A p.P183= | Silent (SNP) | VAF 119/321 reads (37%) | catalogued as rs750810212; called by muse, mutect2, varscan2
- PCSK1N | c.645G>A p.P215= | Silent (SNP) | VAF 191/474 reads (40%) | called by muse, varscan2
- SCUBE2 | c.1602T>C p.A534= | Silent (SNP) | VAF 439/1142 reads (38%) | called by muse, mutect2, varscan2
- SEC14L5 | c.546G>A p.T182= | Silent (SNP) | VAF 179/427 reads (42%) | catalogued as rs192935938, COSV99229472; called by muse, mutect2, varscan2
- TCP11 | c.124+697T>C | Intron (SNP) | VAF 376/927 reads (41%) | called by muse, mutect2, varscan2
